TARGET case TARGET-15-SJMPAL044949 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/14092041-442d-480c-80e6-03e2263c7874

Demographics
Sex at birth: male; Age at index: 12 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 12.2 years (4,471 days); Year of diagnosis: 2009; Days to last follow up: 2,565 days (7.0 years).

Follow-up (1 entry)
- Days to follow up: 2,565 days (7.0 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,565; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 102 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL044949-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 2565
- Protocol: Singapore
- WBC at Diagnosis: 101.9
- Initial Therapy: ALL
- Karyotype: 46,XY,t(8;9)(q?22;p?22)[17]/46,XY[2]
- WHO ALAL Classification: NOS (T/B)
- WHO Dx: NOS (T/B)
